Surgical pathology report (de-identified scan), TCGA case TCGA-76-4932, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Thomas Jefferson University, specimen TCGA-76-4932-01A (Primary Tumor).

[page 1 of 2]
Patient: [REDACTED]

SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS:

1. Left temporal tumor: Glioblastoma multiforme, grade IV of IV (WHO Scale), see microscopic description.
2. Left temporal tumor: glioblastoma multiforme, grade IV of IV (WHO Scale), see microscopic description.

[REDACTED]
Report Electronically Signed

This diagnostic report has been personally interpreted by the signatory of record.

[REDACTED]

Microscopic Description:

The tumor consists of a moderately pleomorphic proliferation of astrocytic cells. There are abundant mitoses as well as endothelial proliferation and necrosis. The findings are diagnostic of a glioblastoma multiforme, grade IV/IV (WHO scale).

Frozen Section Diagnosis:

1. Left temporal tumor: Glioblastoma with extensive necrosis. More tissue requested for permanent sections if clinically indicated

Clinical History and Diagnosis:

[page 2 of 2]
[REDACTED]

Left temporal tumor

Source of Specimen:

- 1: Left temporal tumor
- 2: Left temporal tumor

Gross Description:

[REDACTED]

1. Left temporal tumor: Received fresh for frozen section is a 2 x 0.6 x 0.2 cm fragment of soft, tan-red, irregular tissue. A portion of the specimen is submitted for frozen section. The remaining specimen is entirely submitted for permanent sections. Two cassettes. Touch preps are prepared.
2. Left temporal tumor: Received in formalin are multiple, irregular, brown-gray fragments of rubbery tissue, 5.1 x 3.5 x 1.4 cm in aggregate. The entire specimen is submitted in six cassettes.

Histology Laboratory
H&E

Source: NCI Genomic Data Commons file fc39cb8b-640f-432f-9e3a-71084babbbd7 (TCGA-76-4932.7DD69551-44D6-4B99-B0EF-6EA886B23394.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).